Somatic mutation profile of tumor specimen MBCProject_2346_T2_WES (aliquot MBCProject_2346_T2_WES_1) from CMI case MBCProject_2346, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.8 years (16,733 days).
Specimen MBCProject_2346_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a39be9b5-19f0-4bfc-9b1c-926756abfcff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2346_SALIVA (Saliva), aliquot MBCProject_2346_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0693338b-4f9f-4248-9fd3-3296af9a37e5

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDGF | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.209); catalogued as rs1321277705; called by muse, varscan2
- SPG11 | c.6754+4A>C | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as rs1567127076; called by muse, varscan2
- MMAB | c.*1755C>A | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, varscan2
